Somatic mutation profile of tumor specimen MMRF_1311_1_BM_CD138pos (aliquot MMRF_1311_1_BM_CD138pos_T1_TSE61_L00107) from MMRF case MMRF_1311, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.0 years (21,169 days).
Specimen MMRF_1311_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cfd8060-59e4-4463-bfb8-baada5a90a7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1311_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1311_1_PB_CD3pos_C3_TSE61_L00113; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/756cad6b-1679-40db-9611-0fa71d1e62bb

The open-access MAF lists 63 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 19, Silent 10, Frame Shift Del 3, 5'UTR 2, Intron 1, RNA 1, In Frame Del 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.5730del p.A1911Lfs*6 | Frame Shift Del (DEL) | VAF 32/71 reads (45%) | catalogued as COSV53737764; called by mutect2, pindel, varscan2
- ATM | c.8095C>T p.P2699S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV53743560, COSV53753572; called by muse, mutect2, varscan2
- BRAF | c.1579_1593del p.V527_T531del (on ENST00000288602 / NM_001374244.1; = p.V487_T491del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 15/36 reads (42%) | catalogued as COSV56176207; called by mutect2, pindel, varscan2
- COL18A1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs754701304, COSV100701016; called by muse, mutect2, varscan2
- CTNNB1 | c.1661G>A p.G554D | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV100846208; called by muse, mutect2, varscan2
- ELMO1 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as rs748062510, COSV60299509; called by muse, mutect2, varscan2
- FNIP1 | c.2303G>T p.R768L | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV57200964; called by muse, mutect2, varscan2
- H1-3 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1442181422, COSV99768652; called by muse, mutect2, varscan2
- HSP90B1 | c.211_214del p.E71Sfs*14 | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | catalogued as rs762196975; called by mutect2, pindel, varscan2
- KL | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754248050; called by muse, mutect2, varscan2
- MYOZ3 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs552255058; called by muse, mutect2, varscan2
- PCDHB5 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50647177; called by muse, mutect2, varscan2
- RYR2 | c.14711G>T p.G4904V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63688452; called by muse, mutect2, varscan2
- SPTBN1 | c.6790G>T p.V2264L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV61686131; called by muse, mutect2, varscan2
- TEKT1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768520701; called by muse, mutect2, varscan2
- TIMM44 | c.1239G>A p.P413= | Splice Region (SNP) | VAF 4/48 reads (8%) | catalogued as COSV54494609, COSV99564018; called by muse, mutect2
- ADAMTS20 | c.5235C>A p.D1745E | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- ADGRD1 | c.2479A>G p.T827A | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2
- ANK3 | c.11029A>T p.T3677S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRINP1 | c.306A>T p.Q102H | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- HIPK2 | c.3253C>T p.P1085S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGHMBP2 | c.1580A>G p.D527G | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KLHL14 | c.1877A>G p.Y626C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- MCCC1 | c.13T>G p.S5A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MYRF | c.1151G>T p.G384V (on ENST00000278836 / NM_001127392.3; = p.G375V on NM_013279.4) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR2L8 | c.855C>G p.N285K | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRT | c.3409C>A p.H1137N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TULP1 | c.257_263delinsAC p.T86Nfs*86 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | called by pindel, varscan2*
- ZNF653 | c.923G>T p.C308F | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CHST4 | c.726C>T p.P242= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- CLDN16 | c.420T>G p.V140= | Silent (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- EGR1 | c.103C>T p.L35= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs558452520, COSV53520131; called by muse, mutect2, varscan2
- ERN1 | c.195A>C p.P65= | Silent (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- FNDC1 | c.4560C>T p.H1520= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs574481254; called by muse, mutect2, varscan2
- GLB1 | c.933G>T p.G311= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs1217503175; called by muse, mutect2, varscan2
- GRID1 | c.2769C>T p.T923= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100026019; called by muse, mutect2, varscan2
- HNRNPAB | c.234C>T p.S78= | Silent (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- KRTAP2-4 | c.339C>T p.C113= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs751495363, COSV67458593; called by muse, mutect2, varscan2
- PCDHAC1 | c.2334C>T p.A778= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs782065898, COSV53874590; called by muse, mutect2, varscan2
- AL109910.1 | n.18C>T | RNA (SNP) | VAF 15/23 reads (65%) | catalogued as rs1005989960; called by muse, mutect2, varscan2
- ATG16L1 | c.954+1156A>G | Intron (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- CNNM2 | c.*756G>T | 3'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.*2433A>G | 3'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- EAF1 | c.*284A>G | 3'UTR (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- ETNK2 | c.*854A>G | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- FBXO30 | c.*1090A>T | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- HM13 | c.*28_*40del | 3'UTR (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel
- KCNMB2 | c.*794A>T | 3'UTR (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- MAGEC1 | c.-188C>A | 5'UTR (SNP) | VAF 29/30 reads (97%) | called by muse, mutect2, varscan2
- MANEA | c.*1413A>C | 3'UTR (SNP) | VAF 30/52 reads (58%) | called by muse, mutect2, varscan2
- MLF1 | c.*469C>T | 3'UTR (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- MYF5 | c.*53G>C | 3'UTR (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- PDPR | c.*2679G>T | 3'UTR (SNP) | VAF 35/143 reads (24%) | called by muse, mutect2, varscan2
- PERP | c.*902A>G | 3'UTR (SNP) | VAF 34/67 reads (51%) | catalogued as rs535595115; called by muse, mutect2, varscan2
- RASAL3 | c.-23C>T | 5'UTR (SNP) | VAF 6/29 reads (21%) | called by mutect2, varscan2
- SLC30A4 | c.*2387G>A | 3'UTR (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2
- SLC6A17 | c.*3288C>T | 3'UTR (SNP) | VAF 13/29 reads (45%) | catalogued as rs907453553; called by muse, mutect2, varscan2
- SNTB1 | c.*3075A>T | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SPAST | c.*2360A>C | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- SYT3 | chr19:50639141 G>C | 5'Flank (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- TFAP2B | c.*3821del | 3'UTR (DEL) | VAF 28/58 reads (48%) | catalogued as rs900281241; called by mutect2, varscan2
- TNRC18 | c.*994C>A | 3'UTR (SNP) | VAF 21/29 reads (72%) | called by muse, mutect2, varscan2
- TTL | c.*55G>A | 3'UTR (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
